Somatic mutation profile of tumor specimen ALCH-B0FB-TTP1-A (aliquot ALCH-B0FB-TTP1-A-1-0-D-A709-36) from ALCHEMIST case ALCH-B0FB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.7 years (22,518 days).
Specimen ALCH-B0FB-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be4df140-c803-4131-af3c-dd9a485167f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0FB-NB1-A (Blood Derived Normal), aliquot ALCH-B0FB-NB1-A-1-0-D-A709-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1612d6b-1b0d-49ac-bab1-28d0fb362e92

The open-access MAF lists 35 somatic variants for this specimen: 23 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 8, Intron 2, In Frame Del 2, Splice Site 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 125/758 reads (16%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- BTNL9 | c.590A>G p.E197G | Missense Mutation (SNP) | VAF 44/699 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.334); catalogued as COSV59798353; called by muse, mutect2
- KLRC4 | c.295G>T p.V99L | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs1286567039; called by muse, mutect2
- NOTCH1 | c.3373G>T p.A1125S | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV53070673; called by muse, mutect2
- PAPSS2 | c.1783T>C p.F595L | Missense Mutation (SNP) | VAF 24/563 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1369315688; called by muse, mutect2
- PLD3 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 30/191 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52521450; called by muse, mutect2, varscan2
- SAYSD1 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 23/317 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100010283; called by muse, mutect2
- SYNDIG1 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs369837050; called by muse, mutect2
- WDFY3 | c.1381A>G p.K461E | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1366800400; called by muse, mutect2
- ZMYND8 | c.2869A>G p.I957V (on ENST00000311275 / NM_001363741.2; = p.I931V on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/364 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.065); catalogued as rs755179890; called by muse, mutect2
- AARS2 | c.2072A>C p.D691A | Missense Mutation (SNP) | VAF 14/502 reads (3%) | SIFT tolerated (0.31); PolyPhen benign (0.253); called by muse, mutect2
- ANAPC1 | c.455G>T p.C152F | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANKRD50 | c.2428A>T p.I810F | Missense Mutation (SNP) | VAF 34/470 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2
- GRID2IP | c.2257C>T p.P753S | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2
- MFSD6 | c.168G>T p.W56C | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MORC2 | c.319G>T p.G107C (on ENST00000397641 / NM_001303256.3; = p.G45C on NM_014941.3) | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- MXRA5 | c.6842A>G p.D2281G | Missense Mutation (SNP) | VAF 20/313 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- PPARGC1B | c.79-1G>T p.X27_splice | Splice Site (SNP) | VAF 18/92 reads (20%) | called by mutect2, varscan2
- PRKACA | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- REG1A | c.320A>C p.K107T | Missense Mutation (SNP) | VAF 33/284 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SCN10A | c.2755G>A p.V919I | Missense Mutation (SNP) | VAF 16/338 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.076); called by muse, mutect2
- SLC44A3 | c.203T>G p.F68C (on ENST00000271227 / NM_001114106.3; = p.F20C on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/266 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- TP53 | c.470_481del p.V157_M160del | In Frame Del (DEL) | VAF 21/259 reads (8%) | called by mutect2, pindel
- AARS2 | c.2022A>T p.P674= | Silent (SNP) | VAF 17/418 reads (4%) | called by muse, mutect2
- ARL13B | c.414A>G p.L138= (on ENST00000394222 / NM_001174150.2; = p.L31= on NM_144996.4) | Silent (SNP) | VAF 29/422 reads (7%) | called by muse, mutect2
- DNAJA3 | c.147G>A p.A49= | Silent (SNP) | VAF 18/88 reads (20%) | called by muse, mutect2, varscan2
- KCNH6 | c.198C>T p.C66= | Silent (SNP) | VAF 34/489 reads (7%) | catalogued as rs754730050; called by muse, mutect2
- PPM1D | c.9G>A p.G3= | Silent (SNP) | VAF 20/265 reads (8%) | catalogued as rs1476927978; called by muse, mutect2
- PTPRH | c.1998C>T p.D666= | Silent (SNP) | VAF 9/96 reads (9%) | called by muse, mutect2
- RALGAPA2 | c.4308C>T p.L1436= | Silent (SNP) | VAF 27/152 reads (18%) | catalogued as rs755922090, COSV99173105; called by muse, mutect2, varscan2
- ZBTB38 | c.2055C>T p.D685= | Silent (SNP) | VAF 26/402 reads (6%) | called by muse, mutect2
- AQP1 | c.-27C>T | 5'UTR (SNP) | VAF 16/268 reads (6%) | catalogued as rs772073171; called by muse, mutect2
- PLOD1 | c.77-3327G>T | Intron (SNP) | VAF 12/83 reads (14%) | called by muse, mutect2
- SEM1 | c.*61A>G | 3'UTR (SNP) | VAF 27/298 reads (9%) | called by muse, mutect2
- SYT7 | c.215+4741C>T | Intron (SNP) | VAF 12/194 reads (6%) | called by muse, mutect2
